Surgical pathology report (de-identified scan), TCGA case TCGA-94-A5I6, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Emory, specimen TCGA-94-A5I6-01A (Primary Tumor).

[page 1 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

ICD-0-3
Carcinoma, squamous cell NOS
Site: Lung, lower lobe
JW 2/5/13
LSB 507

* Final Report *

APRPT (Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

DOB:

Gender: M

Acc #:

Pulmonary Big

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. LYMPH NODE, 11L, EXCISION, A1FS:
- ONE BENIGN LYMPH NODE (0/1).
- B. LYMPH NODE, #7, EXCISION, B1FS:
- ONE BENIGN LYMPH NODE (0/1).
- C. LYMPH NODE, ANTERIOR 11L, EXCISION, C1FS:
- ONE BENIGN LYMPH NODE (0/1).
- D. LUNG, LEFT LOWER LOBE, LOBECTOMY, D1FS:
- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (7.2 X 6.2 X 4.2 CM).
- CARCINOMA IS LIMITED TO THE LUNG.
- LYMPH-VASCULAR AND PERINEURAL INVASION ARE NOT IDENTIFIED.
- ALL SURGICAL MARGINS ARE NEGATIVE FOR CARCINOMA.

Printed by:

Printed on:

[page 2 of 5]
Anat Path Reports

* Final Report *

- CARCINOMA IS 1.5 CM FROM THE BRONCHIAL MARGIN.
- THREE BENIGN LYMPH NODES NEGATIVE FOR CARCINOMA (0/3).
- SEE SYNOPTIC REPORT.

E. LYMPH NODE, #6, EXCISION:

- ONE BENIGN LYMPH NODE (0/1).

Comment

Elastic stain performed on block D7 , no pleural invasion by the tumor is identified.

Synoptic Worksheet

D. Left lower lobe; please freeze bronchus margin:

Specimen:	Lobe(s) of lung: Left Lower lobe
Procedure:	Lobectomy
Specimen Integrity:	Intact
Specimen Laterality:	Left
Tumor Site:	Lower lobe
Tumor Focality:	Unifocal
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G2: Moderately differentiated
Tumor Size:	Greatest dimension: 7.2 cm
	Additional dimension: 6.2 cm
	Additional dimension: 4.2 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Not identified
Bronchial Margin:	Uninvolved by invasive carcinoma
	Squamous cell carcinoma in situ (CIS) not identified at bronchial margin
Vascular Margin:	Uninvolved by invasive carcinoma
Parenchymal Margin:	Not applicable
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
All Margins Uninvolved By Invasive Carcinoma:	Distance of invasive carcinoma from closest margin: 15 mm
	Margin closest to invasive carcinoma:: Bronchial
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Not identified
Extranodal Extension:	Not identified

[page 3 of 5]
Anat Path Reports

* Final Report *

TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT3: Tumor greater than 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or Tumor of any size in the main bronchus less than 2 cm distal to the carina but without involvement of the carina; or Tumor of any size associated with atelectasis or obstructive pneumonitis of the entire lung; or Tumors of any size with separate tumor nodule(s) in same lobe
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Nodes examined: 7 Nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified

Clinical History

Left Video-assisted thorascopic surgery, left lower lobectomy. Lung ca

Specimen(s) Received

A: 11L Lymph node
B: #7 Lymph node
C: Anterior 11L Lymph node
D: Left lower lobe; please freeze bronchus margin
E: #6 Lymph node

Gross Description

Specimens A through F are received, each is labeled with the patient's name and medical record number.

Specimen A is received fresh for intraoperative consultation and further labeled "11L lymph node" and consists of a lymph node measuring 2.0 x 1.0 x 0.7 cm along with multiple fragments of soft tissue measuring 2.0 x 0.7 x 0.4 cm in aggregate. The soft tissue fragments are submitted for frozen section in "A1FS." The lymph node is bisected and submitted for frozen section in cassette "A2FS."

Specimen B is received fresh for intraoperative consultation and further labeled "#7 lymph node" and consists of one lymph node measuring 2.7 x 1.8 x 0.8 cm. The specimen is bisected and entirely submitted for frozen section in cassette "B1FS." (Dictated

Specimen C is received fresh for intraoperative consultation and further labeled "anterior 11L lymph node" and consists of multiple fragmented lymph nodes measuring 2.7 x 2.0 x 0.4 cm in aggregate. The specimen is entirely submitted for frozen section in cassette "C1FS."

Specimen D is received fresh for intraoperative consultation and further labeled "left lower lobe" and consists of a lobe of lung weighing (fixed weight) 258.3 grams and measuring 18.0 x 13.2 x 4.9 cm. The pleura is red-purple to pink, and wrinkled with

Printed by:
Printed on:

Page 3 of 5
(Continued)

[page 4 of 5]
Anat Path Reports

* Final Report *

moderate carbonaceous pigmentation. There is a staple line measuring 5.1 cm, just above the hilum. The pleura about the hilum is ragged. There is a firm palpable mass with overlying retracted pleura measuring 7.2 x 6.2 x 4.2 cm. The mass is 1.5 cm from the bronchial margin. The mass upon sectioning has a firm gritty cut surface with areas of necrosis and black pigmentation. The mass abuts, and possibly involves airway, more distal. The mass is 2.2 cm from the stapled margin. The uninvolved parenchyma is red-pink, soft and hemorrhagic, with diffuse mild carbonaceous pigmentation. A small slightly elevated subpleural nodule is identified along the distal medial aspect measuring 0.3 x 0.2 x 0.2 cm. Three peribronchial lymph nodes are identified measuring up to 0.8 x 0.7 x 0.7 cm. The staple line is removed and the parenchymal margin is inked green. The pleural overlying the mass is inked blue. Representative sections are submitted for frozen and permanent sections as stated below in the block summary.

Specimen E is received in formalin, labeled with the patient's name, medical record number and "#6 lymph node" and consists of a black lymph node with attached soft tissue measuring 1.5 x 1.0 x 0.5 cm. The specimen is sectioned and entirely submitted in cassette "E1

CASSETTE SUMMARY:

D1FS: Bronchial margin, shave
D2: Vascular margins, shave
D3-5: Tumor in relation to airway
D6: Tumor in relation to adjacent uninvolved parenchyma
D7: Additional representative tumor in relation to overlying pleura
D8: Uninvolved lung proximal to mass
D9: Uninvolved lung distal to mass
D10: Smaller subpleural nodule, entirely submitted
D11: Three lymph nodes, whole

Intraoperative Consult Diagnosis

A1FS,A2FS: 11L LYMPH NODE (FROZEN SECTION): ONE BENIGN LYMPH NODE, BISECTED. MULTIPLE LYMPH NODE FRAGMENTS NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by and the specimen was received at
B1FS: #7 LYMPH NODE (FROZEN SECTION): ONE BISECTED LYMPH NODE, NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by and the specimen was received at
C1FS: ANTERIOR 11L LYMPH NODE (FROZEN SECTION): FRAGMENTED LYMPH NODE, NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by and the specimen was received at
D1FS: LEFT LOWER LOBE, FREEZE BRONCHIAL MARGIN (FROZEN SECTION): BRONCHIAL MARGIN NEGATIVE FOR CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by and the specimen was received at

Pathologist:

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Page 5 of 5
(End of Report)

Criteria	W 1/24/13	Yes	No

Source: NCI Genomic Data Commons file 682dc98e-0b03-4a97-b5ce-8bec4f5b8ba5 (TCGA-94-A5I6.7780499A-871F-48F5-932A-7E4C0BB62ED1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).